Somatic mutation profile of tumor specimen TCGA-DG-A2KK-01A (aliquot TCGA-DG-A2KK-01A-11D-A17W-09) from TCGA case TCGA-DG-A2KK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 51.6 years (18,834 days).
Specimen TCGA-DG-A2KK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b201f32b-79ac-4373-b422-bb1dbcff1e1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DG-A2KK-10A (Blood Derived Normal), aliquot TCGA-DG-A2KK-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5be8e2ba-515f-4d4b-b0e8-dfc7355f117f

The open-access MAF lists 380 somatic variants for this specimen: 264 protein-altering or splice-affecting, 111 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 111, Nonsense Mutation 30, Splice Site 4, Intron 3, Frame Shift Del 3, 3'Flank 2, Splice Region 2, In Frame Del 1, Translation Start Site 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 34/66 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MFN2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1553141017, COSV52421713; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 53/103 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3119C>G p.A1040G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as COSV57052107; called by muse, mutect2, varscan2
- ABCA7 | c.4405G>T p.D1469Y | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV54027426; called by muse, mutect2, varscan2
- AC011455.2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV55498017, COSV55499215; called by muse, mutect2, varscan2
- ACOT7 | c.325C>T p.R109C (on ENST00000377855 / NM_181864.3; = p.R99C on NM_007274.4) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs201654646, COSV64112946; called by muse, mutect2, varscan2
- ADGRV1 | c.3748G>C p.E1250Q | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV67983003; called by muse, mutect2, varscan2
- ALCAM | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV100065626; called by muse, mutect2, varscan2
- ALDOC | c.7C>G p.H3D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV52024102; called by muse, mutect2, varscan2
- ALKBH1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53659395; called by muse, mutect2, varscan2
- AMD1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV64387223; called by muse, varscan2
- ANAPC2 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.07); catalogued as COSV100119221; called by muse, mutect2, varscan2
- ANK1 | c.4165C>T p.L1389F | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1204896407, COSV55873929; called by muse, mutect2, varscan2
- AP3B1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54877546; called by muse, mutect2
- AR | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as CM015295, COSV65953259; called by muse, mutect2
- ASPSCR1 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV60728143; called by muse, mutect2, varscan2
- ATG2B | c.5778G>C p.Q1926H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55889978; called by muse, mutect2, varscan2
- ATP8B4 | c.455C>G p.S152* | Nonsense Mutation (SNP) | VAF 12/14 reads (86%) | catalogued as COSV52713194, COSV99463125; called by muse, mutect2, varscan2
- BAG4 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1254039818, COSV54859764; called by muse, mutect2, varscan2
- BDP1 | c.6976G>A p.E2326K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as rs780747194, COSV100703662, COSV62430642; called by muse, mutect2, varscan2
- BEST4 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs1308058250, COSV64733784; called by muse, mutect2, varscan2
- BLMH | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1435576751; called by muse, mutect2
- BRINP2 | c.1793C>G p.S598C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100838031, COSV64176850; called by muse, mutect2, varscan2
- BRPF3 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs530180349, COSV60206799, COSV60209946; called by muse, mutect2, varscan2
- BTRC | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV64560950, COSV64563471; called by muse, mutect2, varscan2
- C14orf93 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs775155549, COSV54440710; called by muse, mutect2, varscan2
- C1QTNF4 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1428008920, COSV56783106; called by muse, mutect2, varscan2
- CACNA2D3 | c.839C>G p.S280* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55529014, COSV55540594; called by muse, mutect2, varscan2
- CADPS | c.3946G>C p.E1316Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.202); catalogued as COSV51874730; called by muse, mutect2, varscan2
- CAMK4 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV56668348; called by muse, mutect2, varscan2
- CAMSAP1 | c.4129G>C p.E1377Q | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV56721198; called by muse, mutect2, varscan2
- CARD11 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV67798313; called by muse, mutect2, varscan2
- CATSPERB | c.1409G>C p.G470A | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99831707; called by muse, mutect2
- CBLB | c.2494C>T p.L832F | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV51424767; called by muse, mutect2, varscan2
- CBWD1 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as COSV58699491; called by mutect2, varscan2
- CCDC73 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58794903, COSV58797375; called by muse, mutect2, varscan2
- CCDC93 | c.1627C>A p.H543N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV60120772; called by muse, mutect2, varscan2
- CD248 | c.1802C>G p.S601C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as COSV60936228; called by muse, mutect2, varscan2
- CD79A | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.233); catalogued as COSV55738423; called by muse, mutect2, varscan2
- CD99L2 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100306567, COSV57986852; called by muse, mutect2, varscan2
- CDH8 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs765334615, COSV54848825, COSV54859980, COSV54910773; called by muse, mutect2, varscan2
- CEP350 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62485780; called by muse, mutect2
- CES3 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV57593179, COSV57593454; called by muse, mutect2, varscan2
- CGNL1 | c.2740G>C p.E914Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99849077; called by muse, mutect2
- CHTF18 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV50100169; called by muse, mutect2, varscan2
- CILP2 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.337); catalogued as rs1414797384, COSV52274012; called by muse, mutect2
- CLASP1 | c.2815C>T p.L939F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55320570; called by muse, mutect2, varscan2
- COG1 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs750285470, COSV55429138, COSV55430332; called by muse, mutect2, varscan2
- COL5A1 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs893392661, COSV65667756; called by muse, mutect2, varscan2
- COL5A1 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs371361067, COSV65673223; called by muse, mutect2, varscan2
- CRISPLD2 | c.812G>T p.R271I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV52278494; called by muse, mutect2, varscan2
- CRYBG1 | c.5966G>A p.R1989Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs753275483, COSV64811380; called by muse, mutect2, varscan2
- DENND4C | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756614591, COSV66821923; called by muse, mutect2, varscan2
- DGKZ | c.2672G>C p.G891A (on ENST00000454345 / NM_001105540.2; = p.G703A on NM_003646.4) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV58987066; called by muse, mutect2, varscan2
- DHX9 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62358960; called by muse, mutect2, varscan2
- DNAJC3 | c.1209-1G>C p.X403_splice | Splice Site (SNP) | VAF 32/70 reads (46%) | catalogued as COSV65131002, COSV65131143; called by muse, mutect2, varscan2
- DPP4 | c.2072G>C p.R691T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100859062, COSV62110705; called by muse, mutect2, varscan2
- DQX1 | c.1831G>T p.G611* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV52045644; called by muse, mutect2
- DQX1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.113); catalogued as COSV101099215; called by muse, varscan2
- DYNC1H1 | c.6928G>C p.E2310Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64134169; called by muse, mutect2
- DYRK1A | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.932); catalogued as COSV58705039; called by muse, mutect2, varscan2
- ECEL1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs1188542957, COSV58811472; called by muse, mutect2, varscan2
- ECI2 | c.979C>T p.Q327* (on ENST00000380118 / NM_206836.3; = p.Q297* on NM_006117.2) | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60985922; called by muse, mutect2, varscan2
- EFCAB13 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV58947514; called by muse, mutect2, varscan2
- ELL2 | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52981977; called by muse, mutect2, varscan2
- ELP1 | c.2246G>C p.R749T | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65897145; called by muse, mutect2, varscan2
- EMC1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV64345543; called by muse, mutect2, varscan2
- EMC2 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV55211689, COSV55211745; called by muse, mutect2
- ENOX1 | c.1656G>C p.E552D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV99817059; called by muse, mutect2
- EPHA2 | c.1739-1G>T p.X580_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV64452735, COSV64453091; called by muse, mutect2, varscan2
- EPHA2 | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768995359, COSV64452737, COSV64454553; called by muse, mutect2, varscan2
- EPS8L2 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs558489382, COSV59347472, COSV59347541; called by muse, mutect2, varscan2
- EVI2B | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV100445651; called by muse, mutect2
- FAAP100 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV59884780; called by muse, mutect2, varscan2
- FAM184A | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV58853272; called by muse, mutect2, varscan2
- FARS2 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51166002, COSV51169053; called by muse, mutect2
- FAT4 | c.1427C>G p.S476* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV67884031; called by muse, mutect2, varscan2
- FBN1 | c.2013C>G p.I671M | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV57314065; called by muse, mutect2, varscan2
- FBXO5 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV57670685; called by muse, mutect2, varscan2
- FLNA | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV100775198, COSV61039116; called by muse, mutect2, varscan2
- FNDC1 | c.4397C>T p.P1466L | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs372608984; called by muse, mutect2, varscan2
- FOXA2 | c.1151C>T p.S384L (on ENST00000377115 / NM_153675.3; = p.S390L on NM_021784.5) | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1420632266, COSV65796035; called by muse, mutect2, varscan2
- G2E3 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV52839521; called by muse, mutect2, varscan2
- GAL3ST2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs759350746, COSV51950016; called by muse, mutect2, varscan2
- GBX2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV60445062; called by muse, mutect2, varscan2
- GCNA | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); catalogued as rs763657669, COSV65465767; called by muse, mutect2, varscan2
- GJA1 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV56997592; called by muse, mutect2, varscan2
- GPR156 | c.2005C>G p.Q669E | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100251692; called by muse, mutect2
- GPR179 | c.3664G>A p.G1222R (on ENST00000621958; = p.G1221R on NM_001004334.4) | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.22); catalogued as rs368195290; called by muse, mutect2, varscan2
- GRM1 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs757559798, COSV51126877; called by muse, mutect2, varscan2
- GRXCR1 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as rs772625515, COSV67671175; called by muse, mutect2, varscan2
- GYS2 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53921983; called by muse, mutect2, varscan2
- H2BC9 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as COSV55099491, COSV55099681; called by muse, mutect2, varscan2
- HDAC3 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99781512; called by muse, mutect2, varscan2
- HERC4 | c.3046G>T p.E1016* (on ENST00000395198 / NM_022079.3; = p.E1008* on NM_015601.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV53017705; called by muse, mutect2, varscan2
- HGD | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52197444; called by muse, mutect2, varscan2
- HMCN1 | c.9614G>A p.G3205E | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54891505; called by muse, mutect2, varscan2
- HRNR | c.7472C>G p.S2491C | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100913898; called by mutect2, varscan2
- HTR1A | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756374179, COSV60499954; called by muse, mutect2, varscan2
- IMMT | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1453330097, COSV54479602; called by muse, mutect2, varscan2
- INSRR | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV63872178; called by muse, mutect2, varscan2
- ITPR3 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.582); catalogued as COSV100968077, COSV65411244; called by muse, mutect2
- JCAD | c.3204G>C p.L1068F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV64758991; called by muse, varscan2
- KCNS3 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV58406287; called by muse, mutect2, varscan2
- KLHL28 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100753269; called by muse, mutect2
- KMT2C | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV51427741; called by muse, mutect2, varscan2
- KRT83 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV53339432; called by muse, mutect2, varscan2
- LANCL1 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs780286969, COSV52064869; called by muse, mutect2, varscan2
- LAS1L | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56706894; called by muse, mutect2, varscan2
- LGR5 | c.1360C>G p.H454D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV57004102; called by muse, mutect2, varscan2
- LMBRD1 | c.1448C>T p.S483F (on ENST00000649011; = p.S461F on NM_018368.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100992537, COSV65296787; called by muse, mutect2, varscan2
- LMF2 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs149785243; called by muse, mutect2, varscan2
- LMLN | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV57599556; called by muse, mutect2, varscan2
- LMNB1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54397408; called by muse, mutect2, varscan2
- LRAT | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1042443674, COSV60476888; called by muse, mutect2, varscan2
- LRP1 | c.9668G>A p.R3223H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs369789736; called by muse, mutect2, varscan2
- MAP1A | c.7747G>A p.E2583K | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1379065570, COSV100288567, COSV55807763; called by muse, mutect2, varscan2
- MAPK8IP3 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51718790; called by muse, mutect2, varscan2
- MAST1 | c.2359G>C p.E787Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.334); catalogued as COSV52244642; called by muse, mutect2, varscan2
- MCF2L2 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as rs1172084949, COSV61051965; called by muse, mutect2, varscan2
- MCHR2 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs201793988, COSV56001620; called by muse, mutect2, varscan2
- MDN1 | c.14314G>A p.D4772N | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs373924943; called by muse, mutect2
- MDN1 | c.7288C>T p.L2430F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65517809; called by muse, mutect2, varscan2
- MEP1A | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs565677690, COSV57919344; called by muse, mutect2, varscan2
- MIGA2 | c.1738G>A p.G580R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52976502; called by muse, mutect2
- MRFAP1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as COSV57994810; called by muse, mutect2, varscan2
- MRPS18B | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV52541256; called by muse, mutect2, varscan2
- MTREX | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as rs755494298, COSV57925157; called by muse, mutect2, varscan2
- MUC16 | c.40142G>A p.R13381K | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV66690386, COSV66691108; called by muse, mutect2, varscan2
- MUC16 | c.38462C>G p.S12821C | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.26); catalogued as COSV67458620; called by muse, mutect2, varscan2
- MUC5B | c.7703C>T p.S2568F | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as rs776484432, COSV71591268; called by muse, varscan2
- MUC5B | c.10519C>G p.P3507A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV71591269; called by muse, mutect2, varscan2
- MUC5B | c.13053C>G p.I4351M | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV71591271; called by muse, mutect2, varscan2
- MYBPC2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV63094560; called by muse, mutect2, varscan2
- MYH3 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV56863438; called by muse, mutect2, varscan2
- MYO1H | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV60442476, COSV60444565; called by muse, mutect2
- NAV2 | c.6970C>T p.H2324Y (on ENST00000396087 / NM_001244963.2; = p.H2265Y on NM_145117.5) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60658283; called by muse, mutect2, varscan2
- NDUFA12 | c.84C>T p.F28= | Splice Region (SNP) | VAF 37/124 reads (30%) | catalogued as COSV59846403, COSV59846552; called by muse, mutect2, varscan2
- NEURL4 | c.1811C>G p.S604C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100224618; called by muse, mutect2
- NHLRC2 | c.1070G>A p.W357* | Nonsense Mutation (SNP) | VAF 6/112 reads (5%) | catalogued as COSV100993011; called by muse, mutect2
- NHLRC2 | c.1071G>A p.W357* | Nonsense Mutation (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100993012; called by muse, mutect2
- NHS | c.2834C>G p.S945* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV66273589; called by muse, mutect2, varscan2
- NOTCH4 | c.5929G>C p.E1977Q | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV66679314, COSV66679913; called by muse, mutect2
- NRXN2 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.31); catalogued as rs1286112126, COSV55451044; called by muse, mutect2, varscan2
- NUP153 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV100020799; called by muse, mutect2, varscan2
- OR10H2 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59945774; called by muse, varscan2
- OR10X1 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.125); catalogued as COSV63767237, COSV63767322; called by muse, mutect2, varscan2
- OR4K17 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1347252519, COSV59647769; called by muse, mutect2, varscan2
- P2RY8 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV67177077; called by muse, mutect2, varscan2
- PANK1 | c.1295G>C p.R432T (on ENST00000307534 / NM_148977.2; = p.R207T on NM_138316.4) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56807484; called by muse, mutect2, varscan2
- PARD3 | c.3253G>C p.D1085H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV61053267; called by muse, mutect2, varscan2
- PCDH9 | c.1982T>G p.V661G | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60541659; called by muse, mutect2, varscan2
- PCDHA7 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1383001934, COSV65343356; called by muse, mutect2, varscan2
- PCDHAC2 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53845050; called by muse, mutect2, varscan2
- PCDHB5 | c.2281G>A p.G761S | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs782435177, COSV50649454; called by muse, mutect2, varscan2
- PDHA2 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV54778446, COSV54779009, COSV54779344; called by muse, mutect2, varscan2
- PFN1 | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as COSV99337563; called by muse, mutect2
- PIBF1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV58322080; called by muse, mutect2, varscan2
- PIWIL1 | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as COSV55345738; called by muse, mutect2, varscan2
- PKP4 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV67676548; called by muse, mutect2, varscan2
- PLEKHM2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs1489072993, COSV65395843; called by muse, mutect2, varscan2
- PLXNB1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56488605; called by muse, mutect2, varscan2
- PPP1R12A | c.2552G>A p.R851K | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99700801; called by muse, mutect2
- PRCP | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs771964202, COSV57288280; called by muse, mutect2, varscan2
- PRKD1 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as COSV59564395, COSV59569055; called by muse, mutect2, varscan2
- PRPF8 | c.5938G>A p.E1980K | Missense Mutation (SNP) | VAF 93/250 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59262373; called by muse, mutect2, varscan2
- PRR11 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99231817; called by muse, mutect2
- PSMF1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55673606; called by muse, mutect2, varscan2
- PTCD2 | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV54650095; called by muse, mutect2, varscan2
- PTPRN | c.2211G>C p.K737N | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1387340503, COSV55346811, COSV55347043; called by muse, mutect2, varscan2
- PUM1 | c.3534C>G p.I1178M | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV57083960, COSV99928005; called by muse, mutect2, varscan2
- PVR | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.013); catalogued as COSV51822740; called by muse, mutect2, varscan2
- RALGAPB | c.3676G>A p.D1226N | Missense Mutation (SNP) | VAF 127/331 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.35); catalogued as COSV53436510; called by muse, mutect2, varscan2
- RAVER2 | c.1555G>A p.E519K (on ENST00000294428 / NM_001366165.1; = p.E506K on NM_018211.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.612); catalogued as COSV99605627; called by muse, mutect2
- RBM25 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV56199463; called by muse, mutect2, varscan2
- REEP6 | c.519C>T p.V173= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99278841; called by muse, mutect2, varscan2
- RGS7 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV58536520; called by muse, mutect2, varscan2
- RIMS2 | c.1875A>C p.K625N (on ENST00000666250 / NM_001348490.2; = p.K433N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs757342701, COSV51650241, COSV51670767; called by muse, mutect2, varscan2
- RIMS2 | c.2183C>G p.S728* (on ENST00000666250 / NM_001348490.2; = p.S536* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 77/191 reads (40%) | catalogued as COSV51670807, COSV51686513; called by muse, mutect2, varscan2
- RNF213 | c.1949C>G p.S650* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | catalogued as COSV60621900; called by muse, varscan2
- RPAIN | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV59088772; called by muse, mutect2, varscan2
- RYR2 | c.5443G>A p.E1815K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1294638169, COSV63657858; called by muse, mutect2, varscan2
- SACS | c.12344C>G p.S4115C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66538326; called by muse, mutect2, varscan2
- SAMD3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV60774959, COSV60775188; called by muse, mutect2, varscan2
- SAMD8 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.601); catalogued as COSV65509257; called by muse, mutect2, varscan2
- SCYL3 | c.1858C>T p.P620S (on ENST00000367770; = p.P566S on NM_020423.7) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV53677893, COSV53682783; called by muse, mutect2, varscan2
- SDCCAG8 | c.1722G>A p.M574I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs756420930, COSV100654592, COSV59415446; called by muse, mutect2
- SDF2 | c.450C>G p.F150L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.051); catalogued as COSV99898011; called by muse, mutect2, varscan2
- SECISBP2 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV59393359; called by muse, mutect2, varscan2
- SERPINB4 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV100345974; called by muse, mutect2, varscan2
- SH3RF2 | c.1516C>A p.Q506K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV63038359; called by muse, mutect2, varscan2
- SIK3 | c.3467C>G p.S1156* (on ENST00000445177 / NM_001366686.2; = p.S1114* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV52612277; called by muse, mutect2, varscan2
- SLC19A3 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV51451843; called by muse, mutect2, varscan2
- SLC24A2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV53862341; called by muse, mutect2, varscan2
- SLC4A10 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV55773444; called by muse, mutect2, varscan2
- SLF2 | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.639); catalogued as COSV53272641; called by muse, mutect2
- SOX7 | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58730587; called by muse, mutect2, varscan2
- SREBF1 | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as rs1221052230, COSV55391794; called by muse, mutect2
- SREK1 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV52332482; called by muse, mutect2, varscan2
- SRM | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV65384599; called by muse, mutect2, varscan2
- STAB1 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as COSV58734557; called by muse, mutect2, varscan2
- STAMBPL1 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100904985; called by muse, mutect2
- STAT3 | c.2312G>C p.*771Sext*65 (on ENST00000264657 / NM_001369512.1; = p.*770Sext*65 on NM_003150.4 and 2 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV52886077, COSV52886157; called by muse, mutect2, varscan2
- STK39 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.546); catalogued as COSV63596017; called by muse, mutect2, varscan2
- STKLD1 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV64312210; called by muse, mutect2, varscan2
- SYNE2 | c.10363G>C p.E3455Q | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV59946584; called by muse, mutect2, varscan2
- TBL1X | c.1140G>C p.Q380H | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV54278151; called by muse, mutect2, varscan2
- TBL1XR1 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70500343; called by muse, mutect2, varscan2
- TCAF2 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs771564142, COSV62050747; called by mutect2, varscan2
- TCEA3 | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV71531890; called by muse, mutect2, varscan2
- TCF4 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.905); catalogued as COSV61894052; called by muse, mutect2, varscan2
- TCF7L2 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.705); catalogued as rs892638363, COSV60502738, COSV60504443; called by muse, mutect2, varscan2
- TDRD5 | c.1945C>G p.H649D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.321); catalogued as COSV99677057; called by muse, varscan2
- THOP1 | c.234G>C p.Q78H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs1426677120, COSV57018323; called by muse, mutect2, varscan2
- TIGD3 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs893859728, COSV52888842, COSV99361839; called by muse, mutect2, varscan2
- TNFAIP6 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs777710715, COSV54640199; called by muse, mutect2, varscan2
- TOP2B | c.2265C>G p.F755L (on ENST00000264331 / NM_001330700.2; = p.F750L on NM_001068.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV51970697; called by muse, mutect2, varscan2
- TRA2A | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV51716488; called by muse, varscan2
- TRAV26-1 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs373469394; called by muse, mutect2, varscan2
- TRIP10 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV57570806; called by muse, mutect2, varscan2
- TRPM1 | c.1552A>G p.K518E | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV99856582; called by muse, mutect2, varscan2
- TSPYL5 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59071363; called by muse, mutect2, varscan2
- TTL | c.279G>T p.W93C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746535633, COSV51974076; called by muse, mutect2, varscan2
- TTLL12 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767983108, COSV53357944; called by muse, mutect2
- TTN | c.91430C>G p.S30477* (on ENST00000591111; = p.S23053* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV59984012; called by muse, mutect2, varscan2
- UACA | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV59854926; called by muse, mutect2, varscan2
- UAP1 | c.1501A>G p.K501E (on ENST00000271469 / NM_001324116.1; = p.K484E on NM_003115.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1002143882, COSV99618041; called by muse, mutect2, varscan2
- UHMK1 | c.498G>A p.W166* | Nonsense Mutation (SNP) | VAF 42/97 reads (43%) | catalogued as COSV56419714; called by muse, mutect2, varscan2
- USH2A | c.3203C>G p.S1068C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100241994; called by muse, varscan2
- USP43 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1567647252, COSV53300401; called by muse, mutect2, varscan2
- VCAN | c.7909G>C p.E2637Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV54102569; called by muse, mutect2, varscan2
- VPS13D | c.8629G>C p.E2877Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.067); catalogued as COSV99169317; called by muse, mutect2, varscan2
- WDR35 | c.3445G>T p.E1149* (on ENST00000345530 / NM_001006657.2; = p.E1138* on NM_020779.4) | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as COSV55601808; called by muse, mutect2, varscan2
- WTAP | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV61609795, COSV61609974; called by muse, mutect2, varscan2
- ZACN | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV58035631, COSV58038485; called by muse, varscan2
- ZBTB14 | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV63696464, COSV63697497; called by muse, mutect2, varscan2
- ZC3H12A | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as COSV66104053; called by muse, mutect2, varscan2
- ZMYM3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58737172; called by muse, mutect2, varscan2
- ZNF236 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV53485777; called by muse, mutect2, varscan2
- ZNF236 | c.4619C>A p.S1540* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as COSV53485688, COSV53485796; called by muse, mutect2, varscan2
- ZNF493 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV62749744; called by muse, mutect2
- ZNF516 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV71586890; called by muse, mutect2, varscan2
- ZNF544 | c.1533G>C p.Q511H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as COSV54135291; called by muse, mutect2, varscan2
- ZNF821 | c.327G>C p.L109F (on ENST00000425432 / NM_001376297.1; = p.L67F on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.326); catalogued as COSV57987181; called by muse, mutect2, varscan2
- ZNF831 | c.2839C>T p.Q947* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as rs756845233, COSV100926240, COSV64039068; called by muse, varscan2
- ZNF831 | c.2897C>G p.S966C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.628); catalogued as COSV64039071; called by muse, varscan2
- ZSWIM8 | c.4260G>A p.W1420* (on ENST00000605216 / NM_001242487.2; = p.W1425* on NM_015037.3) | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV55213766; called by muse, mutect2, varscan2
- ZXDC | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs750723904, COSV60446307; called by muse, mutect2, varscan2
- AFF3 | c.3561del p.E1187Dfs*77 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by pindel, varscan2
- ATRX | c.7025_7026del p.V2342Dfs*9 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by pindel, varscan2
- EXTL1 | c.1078_1080del p.K360del | In Frame Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- FAM133B | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- GOLGA6L9 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- HPSE | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2
- NBPF11 | c.2027-1G>A p.X676_splice | Splice Site (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- NRK | c.4210C>T p.P1404S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.418); called by muse, mutect2
- STRC | c.4143G>C p.W1381C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- TADA2A | c.669-1G>C p.X223_splice | Splice Site (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- USP17L2 | c.280dup p.S94Ffs*62 | Frame Shift Ins (INS) | VAF 44/225 reads (20%) | called by mutect2, pindel, varscan2
- ZNF445 | c.2204del p.R735Kfs*122 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- ZNF658 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- AF196969.1 | c.255C>G p.L85= | Silent (SNP) | VAF 68/182 reads (37%) | catalogued as COSV99339396; called by muse, varscan2
- ALG8 | c.1014C>T p.L338= | Silent (SNP) | VAF 44/73 reads (60%) | catalogued as rs1399539947, COSV100220266; called by muse, mutect2, varscan2
- ANKRD50 | c.3093G>C p.L1031= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV72385381; called by muse, mutect2, varscan2
- ANO9 | c.705C>T p.L235= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1311025299, COSV60448979; called by muse, mutect2, varscan2
- AOC2 | c.1710G>C p.L570= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV53825706; called by muse, mutect2, varscan2
- ARIH2 | c.642C>T p.L214= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV62704369; called by muse, mutect2, varscan2
- ASAP1 | c.417G>A p.L139= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV63047070; called by muse, mutect2, varscan2
- AWAT1 | c.369C>T p.F123= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV65738430, COSV65739014; called by muse, mutect2, varscan2
- BEST2 | c.1227G>T p.P409= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV50362084; called by muse, mutect2, varscan2
- C1orf112 | c.1551C>T p.I517= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV53677889; called by muse, mutect2, varscan2
- CACNA1B | c.558C>T p.F186= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as rs565401082, COSV53121089, COSV53121703; called by muse, mutect2, varscan2
- CACNA1E | c.189C>T p.F63= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV62389487; called by muse, mutect2, varscan2
- CAPRIN2 | c.1731C>T p.L577= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs1215251778, COSV51831826; called by muse, mutect2
- CCDC185 | c.804G>A p.K268= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV64820632; called by muse, mutect2, varscan2
- CDH2 | c.1779C>T p.I593= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV52277092; called by muse, mutect2
- CDH26 | c.2076A>G p.A692= (on ENST00000348616 / NM_177980.4; = p.A25= on NM_021810.6) | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV99722921; called by muse, mutect2
- CHST13 | c.381G>A p.L127= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV60043176; called by muse, varscan2
- CNDP1 | c.132C>T p.L44= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV62593617; called by muse, mutect2, varscan2
- CNP | c.564C>T p.L188= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV66367833; called by muse, mutect2, varscan2
- COL20A1 | c.708C>G p.L236= | Silent (SNP) | VAF 57/126 reads (45%) | catalogued as COSV58914885; called by muse, mutect2, varscan2
- CYBB | c.1422C>T p.L474= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV101059816; called by muse, mutect2, varscan2
- DICER1 | c.5736C>G p.L1912= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs995276380, COSV58618039; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAJC16 | c.1653C>T p.F551= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs555387198, COSV65449140; called by muse, mutect2, varscan2
- DOCK2 | c.2838G>A p.Q946= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV56952696; called by muse, mutect2, varscan2
- DUS1L | c.183G>A p.R61= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100152631; called by mutect2, varscan2
- DXO | c.1047C>T p.L349= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100514838; called by muse, mutect2, varscan2
- DYNC1H1 | c.6852G>A p.L2284= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV100795355; called by muse, mutect2
- E4F1 | c.219T>C p.F73= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100066070; called by muse, mutect2, varscan2
- ECM1 | c.1525C>T p.L509= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as rs778523307, COSV60871635, COSV60872479; called by muse, mutect2, varscan2
- ELAVL2 | c.309G>A p.L103= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99807123; called by muse, mutect2, varscan2
- EPHB4 | c.1554C>T p.F518= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs148818692; called by muse, mutect2, varscan2
- ESCO2 | c.66C>T p.F22= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV59414181, COSV59414372; called by muse, mutect2, varscan2
- ESPNL | c.2844C>T p.L948= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs746188069, COSV58032550; called by muse, mutect2, varscan2
- F13A1 | c.1614C>A p.I538= | Silent (SNP) | VAF 83/123 reads (67%) | catalogued as COSV53556837; called by muse, mutect2, varscan2
- FBN2 | c.384C>T p.N128= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV52506248; called by muse, mutect2, varscan2
- FMO2 | c.384C>T p.V128= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV52947274; called by muse, mutect2, varscan2
- FRMD6 | c.1770G>A p.Q590= (on ENST00000344768 / NM_001267046.2; = p.Q582= on NM_152330.4) | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV61087364; called by muse, mutect2, varscan2
- GDF2 | c.573C>T p.F191= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs782720071; called by muse, mutect2, varscan2
- GPAA1 | c.1038C>G p.L346= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV60155554; called by muse, mutect2, varscan2
- GPC1 | c.939C>G p.V313= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV99883198; called by muse, mutect2, varscan2
- GPC1 | c.1230C>T p.A410= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV99883200; called by muse, mutect2, varscan2
- GPI | c.228C>T p.G76= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs150838903; called by muse, mutect2, varscan2
- GPR52 | c.594C>T p.L198= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV52275955; called by muse, mutect2, varscan2
- GSS | c.156C>T p.L52= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs761807612, COSV53812252; called by muse, mutect2, varscan2
- HELZ2 | c.5130C>T p.F1710= (on ENST00000467148 / NM_001037335.2; = p.F1141= on NM_033405.3) | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV71295710; called by muse, mutect2, varscan2
- HLA-C | c.675G>A p.L225= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as COSV66112166; called by muse, mutect2
- HTR4 | c.525C>T p.F175= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV58793080; called by muse, mutect2, varscan2
- HUNK | c.1029G>C p.L343= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV54226872; called by muse, mutect2, varscan2
- IGHG4 | c.843C>T p.D281= | Silent (SNP) | VAF 81/306 reads (26%) | catalogued as rs758157147; called by muse, mutect2, varscan2
- IGSF9 | c.1413C>G p.L471= (on ENST00000368094 / NM_001135050.2; = p.L455= on NM_020789.4) | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV63639615, COSV63640729; called by muse, mutect2, varscan2
- ITIH1 | c.2268C>A p.G756= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV56254569, COSV99835610; called by muse, mutect2
- KCND3 | c.172C>T p.L58= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV56178635; called by muse, varscan2
- KCNJ16 | c.552C>T p.F184= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV52252283, COSV52255295, COSV52257518; called by muse, mutect2, varscan2
- KCTD10 | c.264C>T p.L88= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV57326546; called by muse, mutect2, varscan2
- KDM5B | c.3477C>G p.L1159= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV52506674; called by muse, mutect2, varscan2
- KIDINS220 | c.99G>A p.E33= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV56752159; called by muse, mutect2, varscan2
- KLC3 | c.768G>A p.A256= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs764110677, COSV67267566; called by muse, mutect2, varscan2
- KMT2D | c.10179G>A p.P3393= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs368612015; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- LRBA | c.1960C>T p.L654= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100842054, COSV63953687; called by muse, mutect2, varscan2
- LYAR | c.270C>T p.V90= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs767294372, COSV58642539; called by muse, mutect2, varscan2
- MFSD14B | c.186G>A p.L62= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as COSV64700640; called by muse, mutect2, varscan2
- MIPEP | c.1875C>T p.L625= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1480142823, COSV101193245; called by muse, mutect2, varscan2
- MYH9 | c.5616G>A p.L1872= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53384470; called by muse, mutect2, varscan2
- MYO16 | c.4578C>G p.L1526= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV62748588; called by muse, mutect2, varscan2
- NARS1 | c.1033C>T p.L345= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs1008790123, COSV56876530; called by muse, varscan2
- NFAM1 | c.270G>A p.Q90= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as COSV61194998; called by muse, mutect2, varscan2
- NLRC5 | c.3762G>A p.L1254= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99348154; called by muse, mutect2, varscan2
- NLRP8 | c.192C>T p.L64= | Silent (SNP) | VAF 54/102 reads (53%) | catalogued as rs139646181; called by muse, mutect2, varscan2
- NUP214 | c.5235C>T p.F1745= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100845384; called by muse, mutect2, varscan2
- OTOF | c.4200G>A p.K1400= (on ENST00000272371 / NM_194248.3; = p.K633= on NM_004802.4) | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV55500643; called by muse, mutect2, varscan2
- PANX2 | c.822G>A p.A274= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV50293494; called by muse, mutect2, varscan2
- PCDHA5 | c.1974G>A p.L658= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100972512; called by muse, mutect2
- PHLPP2 | c.2751C>G p.V917= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV100673462; called by muse, mutect2
- PKHD1L1 | c.8547C>T p.F2849= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV65740943; called by muse, mutect2, varscan2
- PRDM9 | c.2292C>G p.L764= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs528650998, COSV57015763; called by muse, varscan2
- RNF144A | c.165C>T p.I55= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100306084; called by muse, mutect2, varscan2
- SARS1 | c.1464T>C p.H488= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV52320431; called by muse, mutect2, varscan2
- SATB2 | c.1635G>T p.L545= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV53481855; called by muse, mutect2, varscan2
- SGSM1 | c.2109C>T p.I703= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV68509621; called by muse, mutect2, varscan2
- SLC12A5 | c.2583C>G p.L861= (on ENST00000454036 / NM_001134771.2; = p.L838= on NM_020708.5) | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as rs768958786, COSV54791524; called by muse, mutect2, varscan2
- SLC35C2 | c.435C>G p.L145= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as rs761975946, COSV99709554; called by muse, mutect2, varscan2
- SLC44A2 | c.519C>T p.F173= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV59836155; called by muse, mutect2, varscan2
- SOCS5 | c.216G>A p.S72= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1210996352, COSV60603637; called by muse, mutect2, varscan2
- SPOCK1 | c.1023C>T p.G341= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV56445397; called by muse, mutect2, varscan2
- SSH2 | c.243C>T p.F81= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV52170134, COSV52177024; called by muse, mutect2, varscan2
- STAB2 | c.6186G>A p.K2062= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs1204671456, COSV66337507; called by muse, mutect2, varscan2
- STARD13 | c.1479C>G p.V493= (on ENST00000336934 / NM_001243476.3; = p.V375= on NM_052851.3) | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV55229322; called by muse, mutect2, varscan2
- STXBP2 | c.1302C>T p.H434= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV99657375; called by muse, mutect2, varscan2
- SUSD2 | c.51C>T p.L17= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs201642977, COSV99573939; called by muse, mutect2, varscan2
- TAF6L | c.1257C>T p.L419= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV53667965; called by muse, mutect2, varscan2
- TCF21 | c.474G>T p.G158= | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as COSV52818151, COSV52818198; called by muse, mutect2, varscan2
- TECPR1 | c.2475G>A p.E825= | Silent (SNP) | VAF 61/149 reads (41%) | catalogued as COSV65783089; called by muse, mutect2, varscan2
- TENM3 | c.7662G>A p.T2554= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1156562267, COSV69299063; called by muse, mutect2, varscan2
- TM9SF4 | c.96C>T p.I32= | Silent (SNP) | VAF 26/282 reads (9%) | catalogued as COSV99455107; called by muse, mutect2
- TMC6 | c.1671C>T p.F557= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs765210208, COSV59807993; called by muse, mutect2, varscan2
- TOP3A | c.2118A>G p.P706= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1567735265, COSV100329294; called by muse, mutect2, varscan2
- TREML2 | c.336C>T p.I112= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as COSV72439081; called by muse, mutect2, varscan2
- TRO | c.2589C>G p.L863= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV51500104; called by muse, mutect2, varscan2
- TSPEAR | c.1683C>T p.I561= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100555366; called by muse, mutect2
- TUBA1B | c.507C>T p.F169= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as rs1177844769, COSV60136713; called by muse, mutect2, varscan2
- UBE2O | c.1653G>A p.T551= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs779667761, COSV60061490; called by muse, mutect2, varscan2
- UBR1 | c.2484G>C p.L828= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99317802; called by muse, mutect2, varscan2
- USP29 | c.471G>C p.V157= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV54141664, COSV54142750; called by muse, mutect2, varscan2
- USP51 | c.2082C>G p.L694= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV72351573; called by muse, mutect2, varscan2
- VAC14 | c.42C>T p.I14= | Silent (SNP) | VAF 56/120 reads (47%) | catalogued as COSV55752598, COSV55753927; called by muse, mutect2, varscan2
- VN1R4 | c.321C>T p.I107= | Silent (SNP) | VAF 89/186 reads (48%) | catalogued as COSV60804638, COSV60804854; called by muse, mutect2, varscan2
- VPS13D | c.6156G>A p.L2052= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV50631665; called by muse, mutect2, varscan2
- VRK3 | c.771G>A p.L257= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV57465388; called by muse, mutect2, varscan2
- ZACN | c.918C>T p.L306= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV58035621; called by muse, varscan2
- ZNF341 | c.1581C>T p.L527= (on ENST00000375200 / NM_001282935.1; = p.L520= on NM_032819.4) | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV61007729; called by muse, mutect2, varscan2
- ZNF831 | c.2829C>T p.L943= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV64039066; called by muse, varscan2
- DNAJC11 | c.704+395G>A | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- GH2 | c.456+125C>T | Intron (SNP) | VAF 36/91 reads (40%) | catalogued as COSV60426631; called by muse, mutect2, varscan2
- MACF1 | c.15832-10648G>T | Intron (SNP) | VAF 14/36 reads (39%) | catalogued as COSV57116455; called by muse, mutect2, varscan2
- URM1 | chr9:128392702 G>A | 3'Flank (SNP) | VAF 31/84 reads (37%) | catalogued as rs757532165; called by muse, mutect2, varscan2
- VAX1 | chr10:117132252 G>C | 3'Flank (SNP) | VAF 6/41 reads (15%) | catalogued as COSV53328604; called by muse, mutect2, varscan2
